Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A94O, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A94O-01A (Primary Tumor).

[page 1 of 2]
Collect date:
(MM/DD/YYYY)

ICD O-3
Adenocarcinoma, intestinal
Type 8/44/3
Site Gastric antrum C16.3
JW 3/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

1- "Product of gastrectomy + pancreatectomy":

- Moderately differentiated adenocarcinoma (intestinal type of Lauren), infiltrating until subserosa adipose tissue
- Maximum dimension of neoplasia: 10.4 cm;
- Angiolymphatic invasion: present;
- Perineural invasion: not detected;
- Surgical margins: uninvolved by neoplasia;
- Pancreas: uninvolved by neoplasia (see note)

Note: Were performed histological sections of pancreas and its area of adherence to the stomach, where was evidenced intense chronic serositis with fibrous proliferation and vascular ectasia.

2- "Greater omentum":

Uninvolved by neoplasia

3- "Splenectomy":

Uninvolved by neoplasia

4- "Esophageal margin":

Uninvolved by neoplasia

5- "Lymph nodes":

Right paracardic: uninvolved by neoplasia (0/2).

Left paracardic: uninvolved by neoplasia (0/4).

Lesser curvature: Involved by neoplasia (5/20).

Short gastric: uninvolved by neoplasia (0/8).

Left gastroepiploics: uninvolved by neoplasia (0/2).

Right gastroepiploics: Involved by neoplasia (2/8).

Suprapylorics: Involved by neoplasia (1/1).

Infrapylorics: Involved by neoplasia (7/11).

Left gastric artery: Involved by neoplasia (1/4).

Anterior hepatic artery: Involved by neoplasia (1/1).

Celiac trunk: Involved by neoplasia (3/3).

Splenic hilum: fragments of fibrous connective and adipose tissue and spleen tissue uninvolved by neoplasia.

Proximal splenic artery: uninvolved by cancer (0/4).

[page 2 of 2]
Distal splenic artery: uninvolved by neoplasia (0/2).
Superior mesenteric vein: uninvolved by neoplasia (0/1).
Hepatoduodenal ligament: fragment of fibrous connective and adipose tissue
uninvolved by neoplasia.

Reviewer Initials	MA	DRG Reviewed: 11/12/13

Source: NCI Genomic Data Commons file 71a89136-11be-4b76-887b-bb353ebd8545 (TCGA-VQ-A94O.CE099405-1E0E-4F94-9305-71E9A54373CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).